Gene-level copy-number profile of tumor specimen ALCH-B4SJ-TTP1-A from ALCHEMIST case ALCH-B4SJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,331 days).
Specimen ALCH-B4SJ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e4ba0c3a-8aff-41f6-9533-7edc20a86b45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4SJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/0b935313-f3f4-4d0a-a28e-9eb7189f762b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 230; copy number 2: 48,433; copy number 3: 9,032; copy number 4: 467; copy number 5: 212; copy number 6: 11; copy number 7: 11; copy number 8: 2; copy number 9: 1; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 240 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:34,209,465–34,871,582, 3 genes, copy number 5 (within-gene range 3–5): AC009262.1, RNU6-438P, NPSR1-AS1.
- chr7:54,330,670–57,153,836, 91 genes, copy number 5–6 (broad region; genes not listed).
- chr11:1,947,278–1,989,920, 2 genes, copy number 8: MRPL23, MRPL23-AS1.
- chr14:105,546,610–105,549,694, 1 gene, copy number 5: ELK2BP.
- chr15:73,752,317–73,770,613, 1 gene, copy number 5 (within-gene range 2–5): INSYN1-AS1.
- chr16:29,475,064–29,505,999, 3 genes, copy number 7: AC133555.2, AC133555.1, NPIPB12.
- chr16:30,267,553–30,335,374, 1 gene, copy number 5: SMG1P5.
- chr16:32,600,299–32,615,639, 1 gene, copy number 9: AC137800.1.
- chr16:32,715,931–32,788,944, 8 genes, copy number 7: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr18:22,347,846–25,352,190, 60 genes, copy number 5: AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr18:32,937,402–33,441,101, 1 gene, copy number 5 (within-gene range 2–5): CCDC178.
- chr18:33,552,123–37,762,131, 61 genes, copy number 5 (broad region; genes not listed).
- chr21:44,133,610–44,210,114, 2 genes, copy number 5 (within-gene range 2–5): GATD3A, LINC01678.
- chr22:18,873,543–18,947,732, 5 genes, copy number 5–11 (within-gene range 2–11): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 230. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
